Somatic mutation profile of tumor specimen TCGA-CV-A6K2-01A (aliquot TCGA-CV-A6K2-01A-11D-A31L-08) from TCGA case TCGA-CV-A6K2, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 79.7 years (29,114 days).
Specimen TCGA-CV-A6K2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 952dc8f7-2885-4f6d-92bb-06d1014a2ca3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-A6K2-10A (Blood Derived Normal), aliquot TCGA-CV-A6K2-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c17d09bc-68c5-4665-a5f2-0071faf585d9

The open-access MAF lists 734 somatic variants for this specimen: 527 protein-altering or splice-affecting, 198 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 458, Silent 198, Nonsense Mutation 50, Splice Site 9, Intron 4, Nonstop Mutation 3, Frame Shift Ins 3, Splice Region 2, 5'UTR 2, In Frame Del 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.738G>C p.M246I | Missense Mutation (SNP) | VAF 19/67 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV52735934, COSV52772732, COSV53038458, COSV53481758; called by muse, mutect2, varscan2
- ABCC2 | c.2879G>T p.G960V | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100966684; called by muse, mutect2, varscan2
- ABHD3 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs200033763, COSV100004303, COSV100004551; called by muse, mutect2, varscan2
- ABI1 | c.1387G>A p.D463N | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.21); PolyPhen probably damaging (1); catalogued as COSV100698064; called by muse, mutect2, varscan2
- ACAD10 | c.999G>A p.M333I | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV100564550; called by muse, mutect2, varscan2
- ACAP3 | c.880C>T p.Q294* | Nonsense Mutation (SNP) | VAF 18/107 reads (17%) | catalogued as COSV100686725; called by muse, mutect2, varscan2
- ACOXL | c.680G>A p.R227K | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100490593; called by muse, mutect2, varscan2
- ADCY10 | c.537G>C p.Q179H | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100897052; called by muse, mutect2, varscan2
- ADGRG4 | c.9096C>G p.I3032M | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as COSV54949175, COSV99796508; called by muse, mutect2, varscan2
- ADRB1 | c.1054G>C p.E352Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.033); catalogued as COSV100992311; called by muse, mutect2, varscan2
- AHCTF1 | c.6473C>T p.S2158L (on ENST00000366508; = p.S2132L on NM_015446.5) | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV100404341; called by muse, mutect2, varscan2
- AJAP1 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65452549; called by muse, mutect2, varscan2
- AJUBA | c.1108G>A p.G370R | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as COSV99401166; called by muse, varscan2
- AK5 | c.1008G>A p.M336I (on ENST00000354567 / NM_174858.3; = p.M310I on NM_012093.4) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100643344; called by muse, mutect2, varscan2
- AK9 | c.872G>A p.R291K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.285); catalogued as COSV99572749; called by muse, mutect2, varscan2
- AKR1B15 | c.960C>G p.F320L | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.066); catalogued as COSV101423404; called by muse, mutect2
- AKR1E2 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100033668; called by muse, mutect2, varscan2
- AL592490.1 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as rs1266468879, COSV101308269; called by muse, mutect2, varscan2
- ALDH1L2 | c.1503G>C p.M501I | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as COSV99311274; called by muse, mutect2, varscan2
- ALYREF | c.781-1G>C p.X261_splice | Splice Site (SNP) | VAF 13/85 reads (15%) | catalogued as COSV100485888; called by muse, mutect2, varscan2
- ANGEL2 | c.141G>C p.W47C | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.57); catalogued as COSV100853988, COSV64736873; called by muse, mutect2, varscan2
- ANK3 | c.8506C>T p.H2836Y | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.018); catalogued as rs199656517, COSV99781862; called by muse, mutect2, varscan2
- ANK3 | c.2891G>A p.S964N (on ENST00000280772 / NM_001320874.2; = p.S98N on NM_001149.3) | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99781968; called by muse, mutect2
- ANKMY1 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1472021219, COSV56030432; called by muse, mutect2, varscan2
- ANKRD12 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV100041981; called by mutect2, varscan2
- ANKRD49 | c.464G>C p.R155T | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100120005; called by muse, mutect2, varscan2
- AOC2 | c.925C>G p.Q309E | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.065); catalogued as COSV99513785; called by muse, mutect2, varscan2
- APOB | c.8356G>A p.E2786K | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs373774326; called by muse, mutect2, varscan2
- AQP4 | c.11G>C p.R4T | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as COSV101270560, COSV101270572; called by muse, mutect2
- ARHGAP10 | c.634C>T p.H212Y | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV100331701; called by muse, mutect2, varscan2
- ARPP21 | c.997G>C p.G333R | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.456); catalogued as COSV99493103; called by muse, mutect2
- ASXL3 | c.5642A>G p.K1881R | Missense Mutation (SNP) | VAF 38/275 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.019); catalogued as rs759812028, COSV99326254; called by muse, mutect2, varscan2
- ATG2B | c.4165G>A p.D1389N | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99952218; called by muse, mutect2, varscan2
- ATP10A | c.2342C>T p.S781L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV100791483; called by muse, mutect2, varscan2
- ATP12A | c.1787C>G p.S596C | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99518334; called by muse, mutect2, varscan2
- ATP2C1 | c.1237G>A p.D413N | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100146951, COSV60752897; called by muse, mutect2, varscan2
- ATP2C2 | c.1298G>A p.G433E | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as COSV52296324; called by muse, mutect2, varscan2
- ATP8B2 | c.2760C>G p.F920L (on ENST00000672630; = p.F887L on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/402 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as rs758880354, COSV59245902; called by muse, mutect2, varscan2
- ATP8B4 | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.318); catalogued as rs771488564, COSV52726608; called by muse, mutect2, varscan2
- B3GALT2 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100813635; called by muse, mutect2, varscan2
- BACH1 | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 24/150 reads (16%) | catalogued as COSV99728636; called by muse, mutect2, varscan2
- BCAT1 | c.691C>T p.L231F | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV99678925; called by muse, mutect2, varscan2
- BICC1 | c.1760C>T p.S587L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV99570846; called by muse, mutect2, varscan2
- BMPER | c.1465C>T p.L489F | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.56); catalogued as COSV99780417; called by muse, mutect2, varscan2
- BORCS5 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100056325; called by muse, varscan2
- BORCS5 | c.162C>G p.I54M | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); catalogued as COSV100056327; called by muse, varscan2
- BPTF | c.4273C>T p.Q1425* | Nonsense Mutation (SNP) | VAF 14/102 reads (14%) | catalogued as COSV100075877; called by muse, mutect2, varscan2
- BRCA1 | c.525G>C p.K175N | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100524907, COSV58797251; called by muse, mutect2, varscan2
- BRD4 | c.1554C>G p.L518= | Splice Region (SNP) | VAF 30/176 reads (17%) | catalogued as COSV99651343; called by muse, mutect2, varscan2
- BRD7 | c.571C>T p.Q191* | Nonsense Mutation (SNP) | VAF 6/88 reads (7%) | catalogued as COSV101164987, COSV101165042; called by muse, mutect2
- BRD9 | c.1705C>T p.R569C | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.245); catalogued as rs758871899, COSV100057545, COSV60248464; called by muse, mutect2, varscan2
- BRIP1 | c.3188C>G p.S1063W | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.955); catalogued as COSV99369164, COSV99370889; called by muse, mutect2, varscan2
- BRSK2 | c.1239C>G p.I413M | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV100373085, COSV57540713; called by muse, mutect2, varscan2
- BTN3A3 | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.687); catalogued as rs200625612, COSV55071353; called by muse, mutect2, varscan2
- C3orf62 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.127); catalogued as rs774667709, COSV55537033; called by muse, mutect2, varscan2
- C5orf15 | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV99198353; called by muse, mutect2, varscan2
- C5orf51 | c.162G>C p.E54D | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV101069047, COSV67565474; called by muse, mutect2, varscan2
- C6 | c.2341G>C p.G781R | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as COSV99667685; called by muse, mutect2, varscan2
- C6orf118 | c.623G>C p.G208A | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.414); catalogued as COSV100025019, COSV57812667, COSV57818107; called by muse, mutect2, varscan2
- C9orf24 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV52625453, COSV99898110; called by muse, mutect2, varscan2
- CACNA1G | c.2071G>A p.E691K | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.107); catalogued as rs768371909, COSV61721112; called by muse, mutect2, varscan2
- CACNA1G | c.5578G>A p.E1860K | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV61722463; called by muse, mutect2, varscan2
- CACNA1S | c.5290G>T p.E1764* | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | catalogued as rs534324858, COSV100755332; called by muse, mutect2, varscan2
- CAPN3 | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 57/293 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.334); catalogued as COSV100533347; called by muse, mutect2, varscan2
- CAPRIN1 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV100404187; called by muse, mutect2, varscan2
- CARD10 | c.1307C>T p.T436M | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs201397783; called by muse, mutect2, varscan2
- CARF | c.1475C>G p.S492* | Nonsense Mutation (SNP) | VAF 17/84 reads (20%) | catalogued as COSV100247853; called by muse, mutect2, varscan2
- CASP6 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99488840; called by muse, mutect2, varscan2
- CASP8 | c.114C>G p.I38M | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99965841; called by muse, mutect2, varscan2
- CASP8 | c.289C>G p.Q97E | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV51848562, COSV51858129; called by muse, mutect2, varscan2
- CASP8 | c.1384C>T p.Q462* (on ENST00000432109 / NM_033355.3; = p.Q479* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 13/81 reads (16%) | catalogued as COSV99630778; called by muse, mutect2, varscan2
- CCDC146 | c.369G>C p.M123I | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV99593078; called by muse, mutect2, varscan2
- CCDC171 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99900728, COSV99901783; called by muse, mutect2, varscan2
- CCDC42 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); catalogued as rs781125276, COSV53448814; called by muse, mutect2, varscan2
- CCDC66 | c.1534G>A p.E512K (on ENST00000394672 / NM_001353147.1; = p.E478K on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100414306; called by muse, mutect2, varscan2
- CCDC74A | c.516C>G p.F172L | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as COSV99723737, COSV99723903; called by muse, mutect2, varscan2
- CCDC81 | c.935C>G p.S312C (on ENST00000445632 / NM_001156474.2; = p.S222C on NM_021827.4) | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.776); catalogued as COSV99564808; called by muse, mutect2
- CD200R1 | c.334G>C p.D112H (on ENST00000471858 / NM_170780.3; = p.D135H on NM_138806.4) | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55599974, COSV99867749; called by muse, mutect2
- CDC25C | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV100086886; called by muse, mutect2, varscan2
- CDK5 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759675039, COSV52525374; called by muse, mutect2, varscan2
- CDKL5 | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 61/173 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV66111451; called by muse, mutect2, varscan2
- CDR1 | c.687G>C p.K229N | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100983448; called by muse, mutect2, varscan2
- CDX2 | c.616C>T p.H206Y | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV66829859; called by muse, mutect2, varscan2
- CECR2 | c.722G>A p.G241D (on ENST00000342247 / NM_001290047.2; = p.G78D on NM_001290046.1) | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99378968; called by muse, mutect2
- CENPM | c.217C>T p.H73Y | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.966); catalogued as COSV99317921; called by muse, mutect2, varscan2
- CEP290 | c.3755C>T p.A1252V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.893); catalogued as rs1189187820, COSV100469624; called by muse, mutect2, varscan2
- CEP41 | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV56221200; called by muse, mutect2, varscan2
- CEP85L | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV100821386; called by muse, mutect2
- CERT1 | c.2012G>T p.R671L (on ENST00000405807 / NM_001130105.1; = p.R543L on NM_005713.3) | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.319); catalogued as COSV54657629, COSV99783677; called by muse, mutect2, varscan2
- CFAP65 | c.2338G>A p.D780N | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as COSV100445836; called by muse, mutect2, varscan2
- CGGBP1 | c.457G>C p.D153H | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV100532045; called by muse, mutect2, varscan2
- CHD3 | c.1711G>C p.E571Q | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100391606; called by muse, mutect2, varscan2
- CHMP7 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV100500742; called by muse, mutect2, varscan2
- CHRM3 | c.641G>C p.R214T | Missense Mutation (SNP) | VAF 45/217 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99699361; called by muse, mutect2, varscan2
- CHST14 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.524); catalogued as COSV100087069; called by muse, mutect2, varscan2
- CHST15 | c.1223C>T p.S408L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as rs375217023; called by muse, mutect2, varscan2
- CIITA | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100162529; called by muse, mutect2
- CKAP5 | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 36/170 reads (21%) | catalogued as COSV100371354; called by muse, mutect2, varscan2
- CLCA2 | c.2200G>C p.E734Q | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.255); catalogued as COSV100991694; called by muse, mutect2, varscan2
- CLCN6 | c.2326G>A p.E776K | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs763864540, COSV100412152; called by muse, mutect2, varscan2
- CLINT1 | c.604G>A p.G202S | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV51624413; called by muse, mutect2, varscan2
- CNDP1 | c.205C>G p.R69G | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100722509, COSV62593269; called by muse, mutect2, varscan2
- COL10A1 | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 29/178 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as rs371683017, COSV99684437; called by muse, mutect2, varscan2
- COPS2 | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV100157378; called by muse, mutect2
- CORO2A | c.1281G>C p.L427F | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100674102; called by muse, mutect2, varscan2
- CREB3L3 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs1008899587, COSV50185205; called by muse, mutect2, varscan2
- CREB3L3 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV99314453; called by muse, mutect2, varscan2
- CREB5 | c.1255-1G>C p.X419_splice (on ENST00000357727 / NM_182898.4; = p.X412_splice on NM_004904.3) | Splice Site (SNP) | VAF 22/66 reads (33%) | catalogued as COSV100744261; called by muse, mutect2, varscan2
- CSMD1 | c.1717C>T p.Q573* (on ENST00000520002; = p.Q572* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV100144606; called by muse, mutect2, varscan2
- CTDSP1 | c.376C>G p.Q126E | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.86); catalogued as COSV99812081; called by muse, mutect2
- CUTC | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV100976182; called by muse, mutect2, varscan2
- CXCL1 | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 28/239 reads (12%) | catalogued as COSV101203945; called by muse, mutect2, varscan2
- CXCL16 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.319); catalogued as COSV99543557; called by muse, varscan2
- CYB5D2 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV100029031; called by muse, mutect2, varscan2
- CYFIP2 | c.2152G>A p.E718K (on ENST00000616178 / NM_001291722.2; = p.E693K on NM_014376.4) | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV100557681; called by muse, mutect2, varscan2
- CYP2C19 | c.1198G>C p.E400Q | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.284); catalogued as COSV100990623, COSV104429003; called by muse, mutect2, varscan2
- CYTH1 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 45/214 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.605); catalogued as COSV100739421; called by muse, mutect2, varscan2
- DCAF6 | c.841G>C p.D281H | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100394771; called by muse, mutect2, varscan2
- DCDC1 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.275); catalogued as COSV100664101; called by muse, mutect2, varscan2
- DCHS1 | c.7853G>C p.G2618A | Missense Mutation (SNP) | VAF 49/235 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100197707; called by muse, mutect2, varscan2
- DCST1 | c.1429G>A p.D477N | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55061345, COSV99665280; called by muse, mutect2, varscan2
- DCSTAMP | c.236G>C p.R79P | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52577499, COSV99886910; called by muse, mutect2, varscan2
- DDX41 | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.195); catalogued as COSV100286799; called by muse, mutect2, varscan2
- DENND3 | c.3536G>C p.R1179T | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99371567; called by muse, mutect2, varscan2
- DKK2 | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 8/64 reads (13%) | catalogued as COSV99569434; called by muse, mutect2
- DLX6 | c.844C>G p.P282A | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0.013); catalogued as rs1223331635, COSV99142495; called by muse, mutect2
- DMXL1 | c.598G>C p.E200Q | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.205); catalogued as COSV100224840; called by muse, mutect2, varscan2
- DMXL2 | c.4690G>A p.E1564K | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51846339; called by muse, mutect2, varscan2
- DNAH5 | c.9320C>T p.S3107L | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54248934; called by muse, mutect2
- DNAH8 | c.5672C>T p.S1891L | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769531980, COSV100546963; called by muse, mutect2, varscan2
- DOCK1 | c.613C>G p.Q205E | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.85); PolyPhen benign (0.041); catalogued as COSV54760269; called by muse, mutect2, varscan2
- DSC2 | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.461); catalogued as COSV99199843; called by muse, mutect2, varscan2
- DSCAML1 | c.910G>C p.E304Q (on ENST00000321322; = p.E244Q on NM_020693.4) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.612); catalogued as COSV100356997; called by muse, mutect2, varscan2
- ECPAS | c.4532C>T p.S1511F | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV99399135; called by muse, mutect2, varscan2
- EFCAB11 | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99965795; called by muse, mutect2, varscan2
- EIF2AK2 | c.315C>G p.I105M | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.058); catalogued as COSV99240949; called by muse, mutect2
- EIF2B1 | c.802G>C p.E268Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV99434770; called by muse, mutect2, varscan2
- EIF2B5 | c.1198G>C p.D400H (on ENST00000647909; = p.D392H on NM_003907.3) | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.287); catalogued as rs1208561560, COSV99889467; called by muse, mutect2, varscan2
- EIF4E1B | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV100024860; called by muse, mutect2, varscan2
- EIF4G2 | c.2355C>A p.N785K | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV101151098, COSV60596220; called by muse, mutect2, varscan2
- ELMO3 | c.1139C>T p.S380L (on ENST00000652269; = p.S327L on NM_024712.5) | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs200639831, COSV99054440; called by muse, mutect2, varscan2
- ENPP7 | c.1147G>C p.E383Q | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as rs147161136, COSV100093662; called by muse, mutect2, varscan2
- EP300 | c.7199C>G p.S2400* | Nonsense Mutation (SNP) | VAF 26/93 reads (28%) | catalogued as COSV99609606; called by muse, mutect2, varscan2
- EPB41L4B | c.1634-1G>C p.X545_splice | Splice Site (SNP) | VAF 24/87 reads (28%) | catalogued as COSV101000942, COSV65802290; called by muse, mutect2, varscan2
- EPHA2 | c.1256C>G p.S419* | Nonsense Mutation (SNP) | VAF 10/104 reads (10%) | catalogued as COSV100626261; called by muse, mutect2, varscan2
- EPHA2 | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs924901221, COSV100626265; called by muse, mutect2, varscan2
- EPX | c.167A>G p.K56R | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99836727; called by muse, mutect2, varscan2
- ERC2 | c.130C>G p.L44V | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV99889033; called by muse, mutect2, varscan2
- ERMARD | c.368C>G p.S123C | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV100824908; called by muse, mutect2, varscan2
- ERO1A | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.821); catalogued as COSV101193660; called by muse, mutect2, varscan2
- ERP29 | c.775G>T p.E259* | Nonsense Mutation (SNP) | VAF 19/170 reads (11%) | catalogued as rs561392506, COSV99923693; called by muse, mutect2, varscan2
- ERV3-1 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV51429913, COSV99276032; called by muse, mutect2, varscan2
- ESCO2 | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | catalogued as COSV100533384; called by muse, mutect2, varscan2
- ETS1 | c.518C>G p.S173W | Missense Mutation (SNP) | VAF 20/223 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs766647712, COSV60092154, COSV60096096; called by muse, mutect2
- EVI5 | c.2432G>C p.*811Sext*4 | Nonstop Mutation (SNP) | VAF 29/201 reads (14%) | catalogued as COSV100945469; called by muse, mutect2, varscan2
- EVPL | c.3805G>A p.E1269K | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757720157, COSV101440965; called by muse, mutect2, varscan2
- EXOSC9 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99697123; called by muse, mutect2, varscan2
- EYA2 | c.802G>C p.E268Q | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100427256, COSV100427311; called by muse, mutect2
- FAM118A | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99343719; called by muse, mutect2, varscan2
- FAM126A | c.981G>C p.W327C | Missense Mutation (SNP) | VAF 34/189 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101327243; called by muse, mutect2, varscan2
- FAM171B | c.2293G>A p.D765N | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as COSV100488950; called by muse, mutect2, varscan2
- FAM184A | c.703G>C p.E235Q | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV100138279; called by muse, mutect2, varscan2
- FAM47C | c.2390C>G p.S797C | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100792920; called by muse, mutect2
- FAM83C | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1474069025, COSV100981684; called by muse, mutect2, varscan2
- FAT1 | c.10211C>G p.S3404* | Nonsense Mutation (SNP) | VAF 9/55 reads (16%) | catalogued as COSV101499314; called by muse, mutect2, varscan2
- FAT1 | c.4480C>T p.Q1494* | Nonsense Mutation (SNP) | VAF 10/69 reads (14%) | catalogued as COSV71674371; called by muse, mutect2, varscan2
- FAT1 | c.3599C>G p.S1200* | Nonsense Mutation (SNP) | VAF 9/88 reads (10%) | catalogued as COSV101499573; called by muse, mutect2, varscan2
- FAT4 | c.5832C>G p.F1944L | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100629904; called by muse, mutect2, varscan2
- FBLN1 | c.785-1G>A p.X262_splice | Splice Site (SNP) | VAF 15/90 reads (17%) | catalogued as COSV99411343, COSV99411434; called by muse, mutect2, varscan2
- FBN2 | c.4303G>A p.A1435T | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV99330230; called by muse, mutect2, varscan2
- FBRS | c.20G>A p.G7E (on ENST00000287468; = p.G527E on NM_001105079.3) | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.732); catalogued as rs1470363539, COSV54918457; called by muse, mutect2, varscan2
- FBXW11 | c.899C>G p.S300C | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99441360; called by muse, mutect2, varscan2
- FBXW8 | c.434C>T p.S145L (on ENST00000309909; = p.S183L on NM_012174.1) | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as COSV99997970; called by muse, mutect2, varscan2
- FKBP7 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.618); catalogued as COSV99247726; called by muse, mutect2
- FLG | c.7930G>C p.E2644Q | Missense Mutation (SNP) | VAF 34/433 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.017); catalogued as COSV100912046; called by muse, mutect2, varscan2
- FLG2 | c.6965C>T p.S2322F | Missense Mutation (SNP) | VAF 46/221 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV101166149; called by muse, mutect2, varscan2
- FLG2 | c.3575C>G p.S1192C | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV101166150; called by muse, mutect2, varscan2
- FMNL3 | c.292-1G>C p.X98_splice | Splice Site (SNP) | VAF 35/156 reads (22%) | catalogued as COSV99526877; called by muse, mutect2, varscan2
- FN1 | c.239G>T p.G80V | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100118085; called by muse, mutect2, varscan2
- FRG1 | c.220G>C p.D74H | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99903835; called by muse, mutect2, varscan2
- FRY | c.252C>G p.I84M | Missense Mutation (SNP) | VAF 51/211 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.041); catalogued as COSV100969832; called by muse, mutect2, varscan2
- FSIP2 | c.20297C>G p.S6766* | Nonsense Mutation (SNP) | VAF 15/80 reads (19%) | catalogued as COSV100556200; called by muse, mutect2, varscan2
- FTSJ3 | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.551); catalogued as rs758822183, COSV100835044; called by muse, mutect2, varscan2
- GALNT11 | c.925G>C p.E309Q | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.141); catalogued as COSV100232016; called by muse, mutect2, varscan2
- GALNTL6 | c.194G>C p.R65T | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV101560457; called by muse, mutect2, varscan2
- GALT | c.46G>C p.E16Q | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.703); catalogued as COSV101122796; called by muse, mutect2, varscan2
- GAS2L1 | c.1597G>C p.E533Q | Missense Mutation (SNP) | VAF 61/356 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV53330814, COSV99329688; called by muse, mutect2, varscan2
- GDI1 | c.45+1G>A p.X15_splice | Splice Site (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100870729, COSV63896442; called by muse, mutect2, varscan2
- GFAP | c.1219C>G p.L407V | Missense Mutation (SNP) | VAF 32/202 reads (16%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.807); catalogued as COSV99493365; called by muse, mutect2, varscan2
- GFRA2 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.966); catalogued as COSV100152051; called by muse, mutect2
- GFRAL | c.616C>T p.H206Y | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100474999; called by muse, mutect2, varscan2
- GIGYF1 | c.683C>G p.S228C | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs775911267, COSV51939424, COSV99309917; called by muse, mutect2, varscan2
- GJA10 | c.947C>G p.S316C | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV101005431; called by muse, mutect2, varscan2
- GJA5 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.226); catalogued as COSV54783772; called by muse, mutect2, varscan2
- GJC3 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.292); catalogued as COSV57210046; called by muse, mutect2, varscan2
- GKAP1 | c.1036G>C p.E346Q | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100897406; called by muse, mutect2
- GLI2 | c.1608C>G p.H536Q (on ENST00000361492 / NM_001374353.1; = p.H553Q on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100084168; called by muse, mutect2, varscan2
- GNAS | c.1777C>T p.Q593* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as COSV58328087; called by muse, varscan2
- GPR12 | c.315C>G p.Y105* | Nonsense Mutation (SNP) | VAF 20/118 reads (17%) | catalogued as COSV101198020; called by muse, mutect2, varscan2
- GPR148 | c.301C>T p.L101F | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.776); catalogued as COSV99998705; called by muse, mutect2, varscan2
- GRID1 | c.1799C>T p.S600L | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.175); catalogued as rs1209326154, COSV100026166; called by muse, mutect2, varscan2
- GRIK1 | c.2257G>C p.E753Q | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100517757; called by muse, mutect2, varscan2
- GRIN2D | c.2182G>A p.D728N | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.47); catalogued as rs752367785, COSV54379307; called by muse, mutect2
- GRK3 | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.116); catalogued as COSV100151960; called by muse, mutect2, varscan2
- GRM3 | c.473C>A p.A158E | Missense Mutation (SNP) | VAF 37/224 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100862821; called by muse, mutect2, varscan2
- GTF2H4 | c.700C>T p.L234F | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99462191; called by muse, mutect2, varscan2
- GTPBP8 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV99868499; called by muse, mutect2, varscan2
- HAUS6 | c.1690G>C p.E564Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.28); catalogued as COSV65839756; called by muse, mutect2, varscan2
- HDLBP | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.139); catalogued as COSV100191715; called by muse, mutect2, varscan2
- HECW1 | c.3662C>G p.S1221C | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV101224210, COSV67827592; called by muse, mutect2, varscan2
- HERC2 | c.3172C>G p.Q1058E | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV99873799, COSV99876418; called by muse, mutect2, varscan2
- HLA-B | c.999G>C p.R333S | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.992); catalogued as COSV101318220; called by muse, mutect2
- HLA-B | c.87G>A p.M29I | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.076); catalogued as COSV101318289; called by muse, mutect2
- HMCN1 | c.5326G>A p.D1776N | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV99634795; called by muse, mutect2, varscan2
- HOOK2 | c.129G>C p.Q43H | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV99317819; called by muse, mutect2, varscan2
- HPN | c.937C>G p.R313G | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.177); catalogued as COSV99385308; called by muse, mutect2
- HSD11B2 | c.929C>T p.S310L | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as rs775550503, COSV99341312; called by muse, mutect2, varscan2
- HSD17B8 | c.755C>T p.S252L | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.538); catalogued as COSV100761857; called by muse, mutect2, varscan2
- HTT | c.449G>A p.C150Y | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61861690; called by muse, mutect2, varscan2
- HUWE1 | c.11311G>A p.E3771K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.899); catalogued as COSV53356677; called by muse, mutect2, varscan2
- HYDIN | c.9275C>T p.S3092L | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99993569; called by muse, mutect2, varscan2
- IARS1 | c.640G>T p.E214* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as rs1286489935, COSV100986881; called by muse, mutect2
- IFT172 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs779572697, COSV53139328; called by muse, mutect2, varscan2
- IGSF9B | c.4027G>C p.E1343Q | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.017); catalogued as COSV100318311; called by muse, mutect2, varscan2
- IL17RB | c.617G>A p.R206K | Missense Mutation (SNP) | VAF 15/183 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99861326; called by muse, mutect2
- IL20RA | c.889G>C p.D297H | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as COSV100360202; called by muse, mutect2
- IQCB1 | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV100182096; called by muse, mutect2, varscan2
- IRF5 | c.1021C>T p.Q341* | Nonsense Mutation (SNP) | VAF 28/190 reads (15%) | catalogued as COSV99977989; called by muse, mutect2, varscan2
- ISG20L2 | c.948G>A p.Q316= | Splice Region (SNP) | VAF 26/146 reads (18%) | catalogued as COSV100494100; called by muse, mutect2, varscan2
- ISM2 | c.1120G>A p.E374K (on ENST00000342219 / NM_199296.3; = p.L258= on NM_182509.4) | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV53634347; called by muse, mutect2, varscan2
- ITCH | c.2530G>A p.D844N (on ENST00000262650 / NM_001257137.3; = p.D803N on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV99393091; called by muse, mutect2, varscan2
- ITFG2 | c.85G>C p.D29H | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs987473725, COSV99958321; called by muse, mutect2, varscan2
- ITGA2 | c.2197C>G p.Q733E | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99671487; called by muse, mutect2, varscan2
- ITGA2 | c.2755G>A p.E919K | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs758465983, COSV56859933, COSV56868278; called by muse, mutect2, varscan2
- ITGAM | c.3182C>T p.S1061L (on ENST00000648685 / NM_001145808.2; = p.S1060L on NM_000632.4) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.038); catalogued as rs1360638469, COSV99793057; called by muse, mutect2, varscan2
- ITIH1 | c.2402G>A p.R801Q | Missense Mutation (SNP) | VAF 45/235 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.051); catalogued as rs144224070, COSV56255906, COSV56257471; called by muse, mutect2, varscan2
- ITPR2 | c.1527G>A p.M509I | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.949); catalogued as COSV67275187; called by muse, mutect2, varscan2
- JADE3 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.856); catalogued as COSV99510227; called by muse, mutect2, varscan2
- KBTBD3 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.863); catalogued as rs889600137, COSV73241300; called by muse, mutect2, varscan2
- KCNH7 | c.1327G>C p.E443Q | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.027); catalogued as COSV59805037; called by muse, mutect2, varscan2
- KDM5B | c.4385C>T p.S1462F | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as rs1019952614, COSV99351268; called by muse, mutect2, varscan2
- KIAA0319 | c.1414G>C p.E472Q | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV100985278, COSV100985773; called by muse, mutect2, varscan2
- KIAA1549L | c.5198C>G p.S1733* (on ENST00000321505; = p.S2030* on NM_012194.3) | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100382232; called by muse, mutect2, varscan2
- KIF5C | c.690G>T p.L230F | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101276195, COSV68483918; called by muse, mutect2
- KIF6 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV99059420, COSV99760432; called by muse, mutect2, varscan2
- KLHL5 | c.1594G>C p.E532Q | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99785778; called by muse, mutect2, varscan2
- KLK2 | c.759C>G p.I253M | Missense Mutation (SNP) | VAF 27/411 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100320040; called by muse, mutect2
- KMT2A | c.6071G>T p.G2024V | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100629697; called by muse, mutect2, varscan2
- KMT2C | c.5750G>A p.R1917K | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV51418580, COSV51525188; called by muse, mutect2, varscan2
- KMT2E | c.4829dup p.L1610Ffs*259 | Frame Shift Ins (INS) | VAF 14/116 reads (12%) | catalogued as rs1243172283; called by mutect2, pindel, varscan2
- KNL1 | c.4770G>C p.L1590F (on ENST00000346991 / NM_170589.5; = p.L1564F on NM_144508.5) | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as COSV100706910; called by muse, mutect2, varscan2
- KNSTRN | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 43/210 reads (20%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.039); catalogued as COSV51105585, COSV99992006; called by muse, mutect2, varscan2
- KRT39 | c.569C>G p.S190C | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100842238, COSV62917513; called by muse, mutect2, varscan2
- LAMA3 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV100557591; called by muse, mutect2, varscan2
- LAMP3 | c.856C>T p.Q286* | Nonsense Mutation (SNP) | VAF 79/314 reads (25%) | catalogued as COSV55614194; called by muse, mutect2, varscan2
- LATS1 | c.1328C>G p.S443* | Nonsense Mutation (SNP) | VAF 60/256 reads (23%) | catalogued as COSV99485829; called by muse, mutect2, varscan2
- LEMD2 | c.1219G>C p.E407Q | Missense Mutation (SNP) | VAF 60/318 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); catalogued as COSV99540883; called by muse, mutect2, varscan2
- LHX9 | c.605C>T p.T202M | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.302); catalogued as rs763846426, COSV100436046; called by muse, mutect2, varscan2
- LILRB5 | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV100300748; called by muse, mutect2, varscan2
- LPA | c.5320G>A p.D1774N | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100307921; called by muse, mutect2, varscan2
- LRIG2 | c.2705G>A p.C902Y | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV100743663; called by muse, mutect2, varscan2
- LRP1 | c.349C>G p.R117G | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs201097198, COSV54507021, COSV99677012; called by muse, mutect2, varscan2
- LRRC43 | c.1641G>C p.K547N | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV100148835; called by muse, mutect2, varscan2
- LRRC8C | c.1582G>C p.D528H | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV100968396; called by muse, mutect2, varscan2
- LTA | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 66/293 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV101403253; called by muse, mutect2, varscan2
- LTV1 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.78); PolyPhen benign (0.006); catalogued as COSV99394688; called by muse, mutect2, varscan2
- MACF1 | c.17506C>T p.H5836Y (on ENST00000372915; = p.H3878Y on NM_012090.5) | Missense Mutation (SNP) | VAF 16/85 reads (19%) | catalogued as COSV99246442; called by muse, mutect2, varscan2
- MAN2B1 | c.1657C>T p.P553S | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as COSV99667271; called by muse, mutect2, varscan2
- MB21D2 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.403); catalogued as rs988241015, COSV66661548, COSV66661553; called by muse, mutect2, varscan2
- MCOLN3 | c.926G>C p.R309T | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100352956; called by muse, mutect2
- MECR | c.1046C>G p.P349R | Missense Mutation (SNP) | VAF 37/187 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as COSV99747367; called by muse, mutect2, varscan2
- MED12L | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 19/98 reads (19%) | catalogued as rs1193700033, COSV99854443; called by muse, mutect2, varscan2
- MED29 | c.535C>T p.P179S (on ENST00000615911; = p.P158S on NM_017592.4) | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as COSV100219272; called by muse, mutect2, varscan2
- MEPCE | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52770070; called by muse, mutect2
- METAP2 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV99704948; called by muse, mutect2, varscan2
- METTL27 | c.253-1G>T p.X85_splice | Splice Site (SNP) | VAF 8/40 reads (20%) | catalogued as COSV99936599; called by muse, mutect2, varscan2
- MGA | c.736C>T p.Q246* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV54951076, COSV99581330; called by muse, mutect2, varscan2
- MGAT2 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.54); catalogued as COSV100023625; called by muse, mutect2, varscan2
- MICAL1 | c.1303G>C p.E435Q | Missense Mutation (SNP) | VAF 68/439 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100668728; called by muse, mutect2, varscan2
- MINAR1 | c.985G>C p.E329Q | Missense Mutation (SNP) | VAF 29/214 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100549195, COSV59586169; called by muse, mutect2, varscan2
- MKRN3 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV58811711; called by muse, mutect2, varscan2
- MKX | c.554C>A p.P185Q | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.439); catalogued as COSV101008837; called by muse, mutect2, varscan2
- MMP21 | c.1501C>T p.H501Y | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100523908; called by muse, mutect2, varscan2
- MMRN1 | c.2878C>T p.Q960* | Nonsense Mutation (SNP) | VAF 18/87 reads (21%) | catalogued as rs1432490830, COSV99307699; called by muse, mutect2, varscan2
- MPP6 | c.866G>C p.R289T | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.269); catalogued as COSV99757805; called by muse, varscan2
- MRTFB | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs369314141, COSV57955911; called by muse, mutect2, varscan2
- MS4A15 | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 40/198 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100558953; called by muse, mutect2, varscan2
- MTERF4 | c.250C>A p.P84T | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.703); catalogued as COSV99612898; called by muse, mutect2, varscan2
- MTHFD1 | c.275C>G p.S92C | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as COSV53698228, COSV99387266; called by muse, mutect2, varscan2
- MUC13 | c.1412C>T p.S471L | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.183); catalogued as rs777807649, COSV100222485; called by muse, mutect2, varscan2
- MUC16 | c.24151C>T p.H8051Y | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.332); catalogued as COSV67495873; called by muse, mutect2, varscan2
- MUC16 | c.19751A>G p.E6584G | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.026); catalogued as COSV101201312; called by muse, mutect2, varscan2
- MUC17 | c.9712G>A p.E3238K | Missense Mutation (SNP) | VAF 92/513 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as COSV60306453; called by muse, mutect2, varscan2
- MYL7 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.91); catalogued as rs1401589720, COSV99790105; called by muse, mutect2, varscan2
- MYO10 | c.2917G>A p.E973K | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.003); catalogued as COSV99946144; called by muse, mutect2, varscan2
- MYO18A | c.4999G>C p.D1667H | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100572642; called by muse, mutect2
- MYO1B | c.638C>G p.S213C | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.081); catalogued as COSV58426928; called by muse, varscan2
- MYOM1 | c.3679G>A p.E1227K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.247); catalogued as COSV99868127; called by mutect2, varscan2
- NAB1 | c.971G>C p.R324T | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.673); catalogued as COSV100493150; called by muse, varscan2
- NCAPD3 | c.1057G>A p.V353I | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs745665288, COSV101596377; called by muse, mutect2, varscan2
- NDUFAF2 | c.376C>G p.Q126E | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV99681681; called by muse, mutect2
- NECTIN3 | c.1309G>A p.D437N | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as COSV100162695; called by muse, mutect2, varscan2
- NEU3 | c.1297C>T p.R433C | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs375818814; called by muse, mutect2, varscan2
- NLN | c.538C>G p.L180V | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV101114457; called by muse, mutect2, varscan2
- NMT1 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.109); catalogued as COSV99364959; called by muse, mutect2, varscan2
- NMT2 | c.802G>C p.E268Q | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100975626; called by muse, mutect2, varscan2
- NOC2L | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.462); catalogued as COSV100498163; called by muse, mutect2, varscan2
- NOG | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 3/14 reads (21%) | catalogued as COSV100240643; called by muse, mutect2
- NPR3 | c.277C>G p.L93V | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as COSV99422379, COSV99423754; called by muse, mutect2
- NR2C2AP | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.631); catalogued as rs1473427937, COSV100284608; called by muse, mutect2, varscan2
- NSMCE2 | c.595G>C p.E199Q | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.07); catalogued as COSV99787327; called by muse, mutect2, varscan2
- NSMCE3 | c.780G>C p.K260N | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99723334; called by muse, mutect2, varscan2
- NUFIP1 | c.256C>T p.L86F | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.996); catalogued as rs777832914, COSV100742136; called by muse, mutect2, varscan2
- OPA1 | c.2899G>C p.E967Q (on ENST00000361510 / NM_130837.3; = p.E912Q on NM_015560.3) | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.17); catalogued as COSV100655451; called by muse, mutect2, varscan2
- OR2W1 | c.724G>A p.G242R | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1341309375, COSV101013901; called by muse, mutect2, varscan2
- OR51V1 | c.158G>A p.W53* | Nonsense Mutation (SNP) | VAF 22/137 reads (16%) | catalogued as COSV58315192; called by muse, mutect2, varscan2
- OR52I2 | c.620C>G p.S207C | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100443007; called by muse, mutect2, varscan2
- OR52K1 | c.843C>G p.F281L | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV100297736, COSV56904811; called by muse, mutect2, varscan2
- OR8J1 | c.843G>T p.L281F | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100275168; called by muse, mutect2, varscan2
- OTX2 | c.471C>G p.I157M (on ENST00000408990 / NM_172337.3; = p.I165M on NM_021728.4) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV59767035; called by muse, mutect2, varscan2
- PARP14 | c.3826C>T p.Q1276* | Nonsense Mutation (SNP) | VAF 13/91 reads (14%) | catalogued as COSV101506340; called by muse, mutect2, varscan2
- PBX2 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.358); catalogued as rs773626213, COSV66708712; called by muse, mutect2, varscan2
- PCMT1 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100953539; called by muse, mutect2, varscan2
- PCNX1 | c.616G>C p.D206H | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV99457000; called by muse, mutect2
- PDE1A | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs1001809091, COSV59520318; called by muse, mutect2, varscan2
- PDIA6 | c.151T>A p.Y51N | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV99694887; called by muse, mutect2, varscan2
- PDX1 | c.366G>T p.M122I | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101124112; called by muse, mutect2, varscan2
- PFKL | c.1768G>A p.D590N | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs781643399, COSV100346187; called by muse, mutect2, varscan2
- PHACTR1 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.587); catalogued as COSV100278622; called by muse, varscan2
- PHLDA3 | c.81G>C p.K27N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1159441328, COSV100943648; called by mutect2, varscan2
- PIGG | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99574285; called by muse, mutect2, varscan2
- PIGQ | c.1166C>T p.S389L | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs1396938371, COSV50318330, COSV99216470; called by muse, mutect2
- PKD1L1 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99221175; called by muse, mutect2, varscan2
- PKHD1L1 | c.5131G>C p.E1711Q | Missense Mutation (SNP) | VAF 46/238 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.374); catalogued as COSV101006741; called by muse, mutect2, varscan2
- PLAT | c.125G>C p.R42T | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV99535369; called by muse, mutect2, varscan2
- PLEKHA5 | c.1693G>C p.E565Q | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV100164674; called by muse, mutect2, varscan2
- PLK2 | c.297G>A p.M99I | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.403); catalogued as COSV99956253; called by muse, mutect2, varscan2
- PLXNC1 | c.1450C>G p.Q484E | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV99313704; called by muse, mutect2, varscan2
- POLDIP3 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99349336; called by muse, mutect2, varscan2
- POLG | c.2155C>G p.L719V | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99175027; called by muse, mutect2, varscan2
- POLG2 | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as rs782544615, COSV99858228; called by muse, mutect2, varscan2
- PPP1R12B | c.1426C>T p.R476W | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs759211358, COSV100408342; called by muse, mutect2, varscan2
- PPP1R13B | c.2648G>A p.R883K | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV99161733; called by muse, mutect2, varscan2
- PPP1R15A | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs368302218; called by muse, varscan2
- PPRC1 | c.4027C>G p.P1343A | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.81); PolyPhen benign (0.01); catalogued as rs1229820106, COSV99532016; called by muse, mutect2, varscan2
- PPRC1 | c.4549C>T p.R1517W | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs776378929, COSV53385256; called by muse, mutect2, varscan2
- PRDM16 | c.1906G>C p.D636H | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.094); catalogued as COSV54608276, COSV99578560; called by muse, mutect2, varscan2
- PRKCE | c.1599G>C p.L533F | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100079275; called by muse, mutect2, varscan2
- PRM2 | c.296G>A p.C99Y | Missense Mutation (SNP) | VAF 19/81 reads (23%) | PolyPhen benign (0.007); catalogued as rs774020331, COSV54113085; called by muse, mutect2, varscan2
- PRPF39 | c.161C>G p.S54C | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.223); catalogued as COSV100866038; called by muse, mutect2, varscan2
- PRPSAP1 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.86); catalogued as rs780467217, COSV100221766, COSV61211814; called by muse, mutect2, varscan2
- PRUNE2 | c.631G>T p.V211F | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100943270; called by muse, mutect2, varscan2
- PTK7 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV100030560; called by muse, mutect2, varscan2
- PTPA | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs200345986; called by muse, mutect2, varscan2
- PTPN12 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV99950659; called by muse, varscan2
- PTPRE | c.2026C>G p.L676V | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV99618912; called by muse, mutect2, varscan2
- PXDNL | c.3529G>T p.D1177Y | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100685948, COSV62501086; called by muse, mutect2, varscan2
- QSOX2 | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs758145655, COSV62394307, COSV62394889; called by muse, mutect2, varscan2
- RAB11A | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.321); catalogued as COSV99976814; called by muse, mutect2, varscan2
- RAB43 | c.57C>G p.F19L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV100167639; called by muse, mutect2
- RAD54L2 | c.1223G>A p.R408K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV99621756; called by muse, mutect2, varscan2
- RASAL3 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs751814881, COSV99484269; called by muse, mutect2, varscan2
- RCL1 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV101099443; called by muse, mutect2, varscan2
- RCOR1 | c.502C>G p.L168V | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51772374, COSV99217757; called by muse, mutect2, varscan2
- RELN | c.3182C>A p.P1061Q | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100634718; called by muse, mutect2, varscan2
- RETSAT | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 30/195 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV55525958, COSV55527501; called by muse, mutect2, varscan2
- REXO5 | c.1400G>C p.R467T | Missense Mutation (SNP) | VAF 44/277 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.526); catalogued as COSV54474376; called by muse, mutect2, varscan2
- RGS12 | c.3309G>C p.E1103D | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.9); catalogued as COSV100123282; called by muse, mutect2, varscan2
- RGS18 | c.448G>C p.E150Q | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs140969834, COSV66509915; called by muse, mutect2
- RGS3 | c.3016-1G>A p.X1006_splice (on ENST00000350696 / NM_001282923.2; = p.X725_splice on NM_130795.4) | Splice Site (SNP) | VAF 9/72 reads (13%) | catalogued as COSV100636954; called by muse, mutect2, varscan2
- RHAG | c.339A>T p.K113N | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV100006834; called by muse, mutect2, varscan2
- RIMKLA | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.231); catalogued as COSV68909858; called by muse, mutect2, varscan2
- ROBO4 | c.1054C>T p.Q352* | Nonsense Mutation (SNP) | VAF 9/64 reads (14%) | catalogued as COSV100127827; called by muse, mutect2
- RPL32 | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV99832842; called by muse, mutect2, varscan2
- RTL8B | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV101195650; called by muse, mutect2, varscan2
- RUFY2 | c.697C>G p.Q233E | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as COSV100700113; called by muse, varscan2
- RYR1 | c.6222G>C p.K2074N | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.241); catalogued as COSV100616799; called by muse, mutect2, varscan2
- SCN4A | c.1367C>A p.A456D | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV101438636; called by muse, mutect2, varscan2
- SCNN1D | c.1902G>C p.E634D (on ENST00000338555; = p.E798D on NM_001130413.4) | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); catalogued as COSV100330246; called by muse, mutect2, varscan2
- SDK1 | c.1087G>C p.E363Q | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV67372940; called by muse, mutect2, varscan2
- SDK2 | c.6118G>A p.E2040K | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV101168427; called by muse, mutect2, varscan2
- SEC16B | c.1051C>G p.Q351E | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0.089); catalogued as COSV100381884; called by muse, mutect2, varscan2
- SEC61A2 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 69/336 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100036617; called by muse, mutect2, varscan2
- SELP | c.1952G>A p.G651E | Missense Mutation (SNP) | VAF 44/293 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99740947; called by muse, mutect2, varscan2
- SEMA4F | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV60282127; called by muse, mutect2, varscan2
- SH3GL2 | c.729-1G>A p.X243_splice | Splice Site (SNP) | VAF 10/39 reads (26%) | catalogued as COSV101014763; called by muse, mutect2, varscan2
- SHROOM3 | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99935197; called by muse, mutect2, varscan2
- SIAH1 | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 9/73 reads (12%) | catalogued as COSV99589469; called by muse, mutect2, varscan2
- SIX4 | c.947C>G p.S316C | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV99382474; called by muse, mutect2, varscan2
- SLAIN2 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.921); catalogued as COSV99971840; called by muse, mutect2, varscan2
- SLC10A1 | c.366G>A p.M122I | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.816); catalogued as COSV99384494; called by muse, mutect2, varscan2
- SLC17A5 | c.995C>T p.S332L | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV63288056; called by muse, mutect2, varscan2
- SLC1A6 | c.319C>G p.L107V | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV55669323; called by muse, mutect2
- SLC26A4 | c.446G>C p.G149A | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99707428; called by muse, mutect2, varscan2
- SLC26A8 | c.153C>G p.I51M | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV100839595; called by muse, mutect2
- SLC39A12 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV66198199; called by muse, mutect2, varscan2
- SLC46A2 | c.1284G>T p.K428N | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV100953503; called by muse, mutect2, varscan2
- SLC4A10 | c.2677G>C p.E893Q (on ENST00000446997 / NM_001354461.2; = p.E863Q on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.547); catalogued as COSV99765495; called by muse, mutect2, varscan2
- SLC5A2 | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV100393387; called by muse, mutect2, varscan2
- SLC5A3 | c.2126G>C p.G709A | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.54); PolyPhen probably damaging (1); catalogued as COSV100758050; called by muse, mutect2, varscan2
- SLC6A19 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs373991930; called by muse, mutect2, varscan2
- SLC6A5 | c.1023C>G p.I341M | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.835); catalogued as COSV54228715; called by muse, mutect2, varscan2
- SLC9A3 | c.1765G>C p.E589Q | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.419); catalogued as COSV53803228, COSV99376575; called by muse, mutect2, varscan2
- SLX4IP | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100570786; called by muse, mutect2, varscan2
- SMC3 | c.2385G>C p.K795N | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.067); catalogued as COSV100700028; called by muse, mutect2, varscan2
- SMG5 | c.596G>A p.R199K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as rs1450031028, COSV100700904; called by muse, mutect2, varscan2
- SMPD3 | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99546007; called by muse, mutect2, varscan2
- SMTNL1 | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as rs369744196; called by muse, mutect2, varscan2
- SNRNP35 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100644586, COSV63471749; called by muse, mutect2, varscan2
- SORL1 | c.4870C>T p.Q1624* | Nonsense Mutation (SNP) | VAF 44/240 reads (18%) | catalogued as COSV99495255; called by muse, mutect2, varscan2
- SP110 | c.205C>G p.L69V | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV104383551, COSV99283740; called by muse, mutect2
- SPECC1 | c.1570G>C p.E524Q | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV99822709; called by muse, mutect2, varscan2
- SPTAN1 | c.7188C>G p.I2396M | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100823964; called by muse, mutect2, varscan2
- SRGAP1 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as rs1180289585, COSV100755075; called by muse, mutect2, varscan2
- ST6GAL1 | c.696G>A p.M232I | Missense Mutation (SNP) | VAF 6/60 reads (10%) | PolyPhen benign (0.001); catalogued as COSV51472804, COSV99399547; called by muse, mutect2
- ST6GALNAC3 | c.917G>C p.*306Sext*1 | Nonstop Mutation (SNP) | VAF 21/120 reads (18%) | catalogued as rs1259641661, COSV60322588; called by muse, mutect2, varscan2
- STRIP2 | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs370580251; called by mutect2, varscan2
- STX12 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.81); catalogued as rs200386519, COSV100881371, COSV64249194; called by muse, mutect2, varscan2
- SUN3 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1487241735, COSV99814317; called by muse, mutect2, varscan2
- SVEP1 | c.5293G>C p.D1765H | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.5); catalogued as COSV52845774; called by muse, mutect2, varscan2
- SVEP1 | c.1466C>A p.P489Q | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.108); catalogued as COSV100238905; called by muse, mutect2, varscan2
- SYNE1 | c.9880G>C p.D3294H (on ENST00000367255 / NM_182961.4; = p.D3301H on NM_033071.3) | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99576328; called by muse, mutect2, varscan2
- SYNE2 | c.15142C>G p.Q5048E | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100648392; called by muse, mutect2, varscan2
- TACC2 | c.6728G>A p.G2243E (on ENST00000334433; = p.G321E on NM_006997.4) | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.201); catalogued as rs1054109938, COSV99587624; called by muse, mutect2, varscan2
- TAF1L | c.3727C>T p.R1243W | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs747277259, COSV54259917; called by muse, mutect2, varscan2
- TAF5L | c.70G>C p.D24H | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV99273588; called by muse, mutect2, varscan2
- TARS3 | c.1082C>G p.S361* | Nonsense Mutation (SNP) | VAF 12/68 reads (18%) | catalogued as COSV100254989; called by muse, mutect2, varscan2
- TDRD3 | c.764G>A p.R255K | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.937); catalogued as COSV52156877, COSV99541117; called by muse, mutect2, varscan2
- TDRD9 | c.2144C>T p.S715L | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.101); catalogued as rs757739389, COSV100175545; called by muse, mutect2, varscan2
- TEPP | c.579C>A p.F193L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV52044102, COSV99333209; called by muse, mutect2, varscan2
- TGFBR2 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as CM064336, COSV55442699; called by muse, mutect2
- THEMIS | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.911); catalogued as COSV100965533; called by muse, mutect2, varscan2
- THUMPD3 | c.1423C>T p.L475F | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100560736; called by muse, varscan2
- THUMPD3 | c.1508G>A p.W503* | Nonsense Mutation (SNP) | VAF 18/120 reads (15%) | catalogued as COSV100560737; called by muse, varscan2
- TJP3 | c.2049C>G p.I683M | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as COSV99516430; called by muse, mutect2
- TLCD3B | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV54227565; called by muse, mutect2, varscan2
- TLN1 | c.5215G>C p.E1739Q | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.103); catalogued as COSV100148170; called by muse, mutect2, varscan2
- TLR4 | c.412C>G p.L138V (on ENST00000355622 / NM_138554.5; = p.L98V on NM_003266.4) | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.217); catalogued as COSV100790690, COSV62922797; called by muse, mutect2, varscan2
- TMEM125 | c.460C>G p.L154V | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101443213; called by muse, mutect2, varscan2
- TMEM61 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 59/262 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV100987762; called by muse, mutect2, varscan2
- TMEM64 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.17); catalogued as rs1346125700, COSV101376087; called by muse, varscan2
- TNIP1 | c.1910G>C p.*637Sext*37 | Nonstop Mutation (SNP) | VAF 11/50 reads (22%) | catalogued as COSV100161734; called by muse, mutect2, varscan2
- TNKS | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 58/316 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs774407820, COSV100127765; called by muse, mutect2, varscan2
- TNKS1BP1 | c.5151C>G p.N1717K | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV100836244; called by muse, mutect2, varscan2
- TNNT2 | c.139G>C p.E47Q | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.478); catalogued as COSV99372503; called by muse, mutect2, varscan2
- TNRC6B | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.112); catalogued as COSV100110388; called by muse, mutect2, varscan2
- TNS4 | c.1430C>G p.S477C | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV54187233, COSV54189069; called by muse, mutect2, varscan2
- TOB2 | c.514C>G p.Q172E | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); catalogued as COSV100548491; called by muse, mutect2, varscan2
- TOX4 | c.1133C>G p.S378C | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as COSV99398561; called by muse, mutect2, varscan2
- TPD52L2 | c.187C>G p.L63V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV99410862; called by muse, mutect2, varscan2
- TRIM25 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs1216733443, COSV100381113; called by muse, mutect2, varscan2
- TRIM42 | c.650G>C p.R217P | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV99648773; called by muse, mutect2, varscan2
- TRIM5 | c.255G>C p.L85F | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV100000662; called by muse, mutect2, varscan2
- TRIM62 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as COSV99357959; called by muse, mutect2, varscan2
- TRIP11 | c.3467G>A p.R1156K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.019); catalogued as COSV99971103; called by muse, mutect2, varscan2
- TRMT61A | c.795C>G p.F265L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV100149436; called by muse, mutect2, varscan2
- TRPC3 | c.361G>T p.E121* (on ENST00000379645 / NM_001366479.2; = p.E48* on NM_003305.2) | Nonsense Mutation (SNP) | VAF 12/81 reads (15%) | catalogued as COSV53377515, COSV99313419; called by muse, mutect2, varscan2
- TRPC5 | c.1906G>A p.D636N | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99462541; called by muse, mutect2, varscan2
- TRPM3 | c.4909G>A p.E1637K (on ENST00000357533 / NM_001366142.2; = p.E1492K on NM_020952.6) | Missense Mutation (SNP) | VAF 116/694 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100678544; called by muse, mutect2, varscan2
- TTBK1 | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52494343, COSV99445456; called by muse, mutect2, varscan2
- TTC13 | c.918C>G p.F306L | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.844); catalogued as COSV100792999; called by muse, mutect2, varscan2
- TTC26 | c.1586G>C p.R529T | Missense Mutation (SNP) | VAF 23/189 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.261); catalogued as COSV100571147; called by muse, mutect2, varscan2
- TTN | c.33883G>A p.E11295K (on ENST00000591111; = p.E10368K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | PolyPhen benign (0.036); catalogued as COSV100627064; called by muse, mutect2
- TTN | c.21281G>A p.R7094K (on ENST00000591111; = p.R6167K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | PolyPhen benign (0.033); catalogued as COSV100599330, COSV60070217; called by muse, mutect2
- TUBGCP3 | c.275C>G p.S92* | Nonsense Mutation (SNP) | VAF 7/53 reads (13%) | catalogued as COSV99997194; called by muse, mutect2, varscan2
- USB1 | c.603C>G p.F201L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99540430; called by muse, mutect2, varscan2
- USP34 | c.4171T>A p.S1391T | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV101277185; called by muse, mutect2, varscan2
- UTP20 | c.7831G>A p.E2611K | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV99882421; called by muse, mutect2, varscan2
- VCAN | c.2684C>T p.S895L | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV99427093; called by muse, mutect2, varscan2
- VEPH1 | c.1252G>T p.A418S | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV100747971; called by muse, mutect2, varscan2
- VIL1 | c.94G>T p.V32F | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV99945841; called by muse, mutect2, varscan2
- VPS33B | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs376313815, COSV60979404, COSV60981548; called by muse, mutect2
- VPS36 | c.584C>G p.S195* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV100955259, COSV100955282; called by muse, mutect2, varscan2
- VWA2 | c.1412G>C p.R471P | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100073942; called by muse, mutect2, varscan2
- VWA8 | c.4414G>C p.E1472Q | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV101022923; called by muse, mutect2, varscan2
- WASHC4 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV100162731; called by muse, mutect2, varscan2
- WDR19 | c.2232C>A p.S744R | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV99975890; called by muse, mutect2, varscan2
- WDR20 | c.1463C>G p.S488C | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV100085425; called by muse, mutect2, varscan2
- WDR55 | c.585C>G p.F195L | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.974); catalogued as COSV100298262; called by muse, mutect2, varscan2
- WIF1 | c.385C>G p.H129D | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99683365; called by muse, mutect2, varscan2
- WWP1 | c.2300G>A p.R767Q | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777777787, COSV55365881; called by mutect2, varscan2
- YIPF3 | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 20/123 reads (16%) | catalogued as COSV100397101, COSV58304973; called by muse, mutect2, varscan2
- YME1L1 | c.2236C>T p.L746F (on ENST00000326799 / NM_139312.3; = p.L689F on NM_014263.4) | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58761519; called by muse, mutect2, varscan2
- YTHDF1 | c.1666C>G p.R556G | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100945618; called by muse, mutect2, varscan2
- YY2 | c.365C>G p.S122C | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV100810839, COSV63410802; called by muse, mutect2, varscan2
- ZBBX | c.787C>T p.Q263* | Nonsense Mutation (SNP) | VAF 38/175 reads (22%) | catalogued as COSV100284831; called by muse, mutect2, varscan2
- ZBTB9 | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs372690660, COSV67701914; called by muse, mutect2, varscan2
- ZC3H6 | c.799C>T p.Q267* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV100674810; called by muse, mutect2, varscan2
- ZCRB1 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as COSV56891950; called by muse, mutect2, varscan2
- ZFAND6 | c.277C>G p.Q93E | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV99928871; called by muse, mutect2, varscan2
- ZFP42 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100479134; called by muse, mutect2, varscan2
- ZFP91 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.954); catalogued as COSV60162124; called by muse, mutect2, varscan2
- ZMYND19 | c.205C>T p.H69Y | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100057295; called by muse, mutect2, varscan2
- ZNF253 | c.476C>G p.S159* | Nonsense Mutation (SNP) | VAF 7/44 reads (16%) | catalogued as COSV100849581; called by muse, mutect2, varscan2
- ZNF276 | c.1263G>C p.K421N (on ENST00000443381 / NM_001113525.2; = p.K346N on NM_152287.4) | Missense Mutation (SNP) | VAF 62/318 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV99235302; called by muse, mutect2, varscan2
- ZNF284 | c.952G>C p.D318H | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV101399076; called by muse, mutect2, varscan2
- ZNF292 | c.2870C>G p.S957* | Nonsense Mutation (SNP) | VAF 5/92 reads (5%) | catalogued as COSV100371047, COSV100371416; called by muse, mutect2
- ZNF322 | c.1069G>C p.D357H | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as COSV101338498; called by mutect2, varscan2
- ZNF335 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100533324; called by muse, mutect2, varscan2
- ZNF384 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.214); catalogued as COSV100158418; called by muse, mutect2, varscan2
- ZNF441 | c.713C>G p.S238C | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs777604162, COSV100777458, COSV63540825; called by muse, mutect2
- ZNF479 | c.521G>C p.R174T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); catalogued as COSV100483016; called by mutect2, varscan2
- ZNF565 | c.1331C>G p.S444* (on ENST00000355114; = p.S404* on NM_152477.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 12/88 reads (14%) | catalogued as COSV100411985; called by muse, mutect2, varscan2
- ZNF599 | c.745C>A p.H249N | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100251288; called by muse, mutect2, varscan2
- ZNF687 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.084); catalogued as COSV100134546; called by muse, mutect2, varscan2
- ZNF700 | c.453C>G p.H151Q | Missense Mutation (SNP) | VAF 49/267 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.869); catalogued as COSV99583761; called by muse, mutect2, varscan2
- ZNF700 | c.796C>G p.Q266E | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.339); catalogued as COSV99583763; called by muse, mutect2, varscan2
- ZNF763 | c.409C>G p.Q137E (on ENST00000358987 / NM_001367172.2; = p.Q140E on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/233 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV100676197; called by muse, mutect2, varscan2
- ZNF765 | c.1436C>T p.S479L | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV101125554; called by muse, mutect2
- ZNF77 | c.1514C>T p.S505L | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs112261253; called by muse, mutect2, varscan2
- ZNFX1 | c.2587A>T p.M863L | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV100870998; called by muse, mutect2, varscan2
- ZSCAN10 | c.1645C>T p.R549W (on ENST00000252463; = p.R604W on NM_032805.3) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1419549276, COSV99374298; called by muse, mutect2, varscan2
- ACACA | c.721G>T p.A241S | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- AJUBA | c.1082_1085del p.T361Sfs*48 | Frame Shift Del (DEL) | VAF 33/184 reads (18%) | called by pindel, varscan2
- AP2B1 | c.2074G>A p.D692N | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- BOP1 | c.1942G>A p.D648N | Missense Mutation (SNP) | VAF 14/217 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- CLEC14A | c.1186T>G p.S396A | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.408); called by mutect2, varscan2
- CSDE1 | c.2246_2248del p.R749del (on ENST00000358528 / NM_001007553.3; = p.R718del on NM_007158.6) | In Frame Del (DEL) | VAF 5/57 reads (9%) | called by mutect2, pindel
- FBXW8 | c.365+1dup | Frame Shift Ins (INS) | VAF 25/109 reads (23%) | called by mutect2, pindel, varscan2
- IGHM | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | called by muse, mutect2, varscan2
- MTX2 | c.488G>A p.W163* | Nonsense Mutation (SNP) | VAF 7/80 reads (9%) | called by muse, mutect2
- OTUD7A | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- PIGW | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- TRBV4-1 | c.102G>T p.M34I | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- UNG | c.273dup p.V92Rfs*51 (on ENST00000242576 / NM_080911.3; = p.V83Rfs*51 on NM_003362.4) | Frame Shift Ins (INS) | VAF 14/164 reads (9%) | called by mutect2, pindel
- WASHC1 | c.739C>A p.P247T | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF654 | c.3376G>T p.E1126* | Nonsense Mutation (SNP) | VAF 10/61 reads (16%) | called by muse, mutect2
- ADAMTS13 | c.3933G>A p.V1311= | Silent (SNP) | VAF 24/108 reads (22%) | catalogued as COSV99390435; called by muse, mutect2, varscan2
- ADAP2 | c.990C>T p.L330= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as rs768129946, COSV100437329; called by muse, mutect2, varscan2
- AFDN | c.2739G>A p.L913= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as COSV100653471; called by muse, mutect2, varscan2
- AHNAK2 | c.15003C>T p.I5001= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV100318771; called by muse, mutect2
- AHNAK2 | c.972C>T p.L324= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100318772; called by muse, mutect2, varscan2
- AKAP3 | c.354G>A p.G118= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as COSV99962561; called by muse, mutect2, varscan2
- AKR1E2 | c.882C>T p.L294= | Silent (SNP) | VAF 22/121 reads (18%) | catalogued as COSV100033670; called by muse, mutect2, varscan2
- ALMS1 | c.990G>C p.L330= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV100043465; called by muse, mutect2
- ALPK2 | c.522C>G p.L174= | Silent (SNP) | VAF 51/230 reads (22%) | catalogued as COSV100864751; called by muse, mutect2, varscan2
- AMBRA1 | c.558G>A p.V186= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV54055551; called by muse, mutect2, varscan2
- ANPEP | c.2388C>G p.V796= | Silent (SNP) | VAF 35/231 reads (15%) | catalogued as rs1240633258, COSV100263460; called by muse, mutect2, varscan2
- ANXA11 | c.762G>C p.L254= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV99627491; called by muse, mutect2, varscan2
- AQR | c.2544G>A p.R848= | Silent (SNP) | VAF 7/126 reads (6%) | catalogued as COSV99334559; called by muse, mutect2
- ARHGAP19 | c.1008C>G p.L336= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV100363311; called by muse, mutect2, varscan2
- ASTN1 | c.2631C>G p.V877= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as COSV99922849; called by muse, mutect2, varscan2
- ASXL3 | c.1611A>G p.L537= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV99326252; called by muse, mutect2
- ATP1A1 | c.3031C>A p.R1011= | Silent (SNP) | VAF 30/115 reads (26%) | catalogued as COSV55193807, COSV99814737; called by muse, mutect2, varscan2
- ATP5MC1 | c.309C>G p.L103= | Silent (SNP) | VAF 70/305 reads (23%) | catalogued as COSV100582423; called by muse, mutect2, varscan2
- ATP7B | c.4275C>T p.V1425= | Silent (SNP) | VAF 26/146 reads (18%) | catalogued as COSV99666901; called by muse, mutect2, varscan2
- BAZ2A | c.4845G>A p.E1615= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99467499; called by muse, mutect2, varscan2
- BEST3 | c.396C>T p.V132= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as COSV99876362; called by muse, mutect2, varscan2
- CABP7 | c.540C>T p.I180= | Silent (SNP) | VAF 26/146 reads (18%) | catalogued as COSV99334907; called by muse, mutect2, varscan2
- CAMTA1 | c.3354T>C p.C1118= | Silent (SNP) | VAF 35/178 reads (20%) | catalogued as rs940083559, COSV100352199; called by muse, mutect2, varscan2
- CASS4 | c.498G>A p.L166= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV100824893; called by muse, mutect2, varscan2
- CCDC171 | c.2736C>G p.L912= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as rs755795384, COSV99901785; called by muse, mutect2, varscan2
- CCDC180 | c.1068C>T p.L356= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as COSV100827270; called by muse, mutect2, varscan2
- CCDC81 | c.753C>T p.T251= (on ENST00000445632 / NM_001156474.2; = p.T161= on NM_021827.4) | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV99564799; called by muse, mutect2, varscan2
- CD3E | c.420C>T p.I140= | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as COSV62346953; called by muse, mutect2, varscan2
- CFAP100 | c.846C>T p.L282= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as COSV100729394; called by muse, mutect2, varscan2
- CLDN23 | c.54C>G p.L18= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV101093178; called by muse, mutect2, varscan2
- COL11A2 | c.1188C>T p.L396= (on ENST00000341947 / NM_080680.3; = p.L289= on NM_080679.2) | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as rs532305958, COSV100554458; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL4A1 | c.4218G>A p.Q1406= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV101011503; called by muse, mutect2, varscan2
- COQ10B | c.30G>A p.L10= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as COSV55836935; called by muse, mutect2, varscan2
- CXCL16 | c.654C>T p.L218= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV99543560; called by muse, varscan2
- CXCL2 | c.258C>G p.L86= | Silent (SNP) | VAF 20/115 reads (17%) | catalogued as COSV99933194; called by muse, mutect2, varscan2
- CYP3A43 | c.612G>A p.L204= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as COSV99733614; called by muse, mutect2, varscan2
- DCST2 | c.1230C>T p.F410= | Silent (SNP) | VAF 22/146 reads (15%) | catalogued as COSV99792209; called by muse, mutect2, varscan2
- DMRTA2 | c.687G>A p.S229= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV101288898; called by muse, mutect2, varscan2
- DNAH17 | c.13257G>A p.K4419= | Silent (SNP) | VAF 33/172 reads (19%) | catalogued as COSV99428491; called by muse, mutect2, varscan2
- DNAH17 | c.375G>A p.E125= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV101103248; called by muse, mutect2
- DNAJB13 | c.633C>T p.I211= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as COSV100334544; called by muse, mutect2, varscan2
- DNAJC11 | c.1506C>T p.I502= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV99275919; called by muse, mutect2, varscan2
- DOCK8 | c.3117G>A p.Q1039= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV101210055; called by muse, mutect2, varscan2
- EIF2D | c.24C>G p.V8= | Silent (SNP) | VAF 17/130 reads (13%) | catalogued as COSV99663015; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.2415C>G p.L805= | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as COSV100349366; called by muse, mutect2
- EIF4ENIF1 | c.2271C>T p.S757= | Silent (SNP) | VAF 15/146 reads (10%) | catalogued as COSV100349368; called by muse, mutect2
- EIF4H | c.591C>T p.F197= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV99733651; called by muse, mutect2, varscan2
- EMP3 | c.306C>G p.L102= | Silent (SNP) | VAF 16/146 reads (11%) | catalogued as COSV53156465, COSV53159578; called by muse, mutect2, varscan2
- ESRP1 | c.429C>T p.F143= | Silent (SNP) | VAF 23/107 reads (21%) | catalogued as rs746386987, COSV100619576; called by muse, mutect2, varscan2
- EXOG | c.18C>T p.I6= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV55063311; called by muse, mutect2
- EXTL2 | c.465C>T p.I155= | Silent (SNP) | VAF 21/109 reads (19%) | catalogued as COSV100921134; called by muse, mutect2, varscan2
- FAT4 | c.492C>T p.I164= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV101272664; called by muse, mutect2, varscan2
- GCN1 | c.2664G>A p.L888= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as rs757332997, COSV100325897; called by muse, mutect2, varscan2
- GLIS2 | c.106C>T p.L36= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs1227691577, COSV99267793; called by muse, mutect2, varscan2
- GPR39 | c.861G>A p.L287= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as COSV100258440; called by muse, mutect2, varscan2
- GPR78 | c.804C>T p.F268= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as rs772135205, COSV101223991; called by muse, mutect2, varscan2
- GRB14 | c.966C>T p.L322= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as rs574967446, COSV99814411; called by muse, mutect2, varscan2
- HNRNPUL1 | c.228G>A p.A76= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV99647566; called by muse, mutect2
- HPN | c.822G>A p.Q274= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs746005036, COSV99385306; called by muse, mutect2, varscan2
- HPS6 | c.219C>T p.A73= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as rs745869412, COSV100154989; called by muse, varscan2
- HSDL2 | c.372G>A p.V124= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as COSV99357106; called by muse, mutect2, varscan2
- IER2 | c.165C>G p.L55= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV99460303; called by muse, mutect2, varscan2
- IGSF10 | c.879G>C p.L293= | Silent (SNP) | VAF 20/131 reads (15%) | catalogued as COSV56789467; called by muse, mutect2, varscan2
- INTS4 | c.2355C>A p.P785= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as COSV100490104, COSV59021191; called by muse, mutect2, varscan2
- ITPR3 | c.1449C>A p.V483= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV100968034; called by muse, mutect2, varscan2
- KALRN | c.1623C>T p.F541= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV99566967; called by muse, mutect2, varscan2
- KCNH8 | c.3057G>A p.T1019= | Silent (SNP) | VAF 41/248 reads (17%) | catalogued as rs375400626; called by muse, mutect2, varscan2
- KDM5A | c.2880G>A p.K960= | Silent (SNP) | VAF 25/133 reads (19%) | catalogued as COSV101239039; called by muse, mutect2, varscan2
- KDSR | c.471C>T p.I157= | Silent (SNP) | VAF 19/123 reads (15%) | catalogued as COSV100430336; called by muse, mutect2, varscan2
- KRT9 | c.870G>A p.K290= | Silent (SNP) | VAF 25/167 reads (15%) | catalogued as COSV55854400, COSV99879347; called by muse, mutect2, varscan2
- LAMA3 | c.3375C>A p.G1125= | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as COSV100557593; called by muse, mutect2, varscan2
- LATS1 | c.1132C>T p.L378= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV53597585; called by muse, mutect2, varscan2
- LHX3 | c.168C>G p.L56= (on ENST00000371748 / NM_178138.6; = p.L61= on NM_014564.5) | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV100871278; called by muse, mutect2, varscan2
- LHX9 | c.288G>A p.L96= | Silent (SNP) | VAF 75/385 reads (19%) | catalogued as COSV100436044; called by muse, mutect2, varscan2
- LRRC2 | c.516C>G p.L172= | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as COSV99947623; called by muse, mutect2, varscan2
- MAB21L2 | c.474C>G p.V158= | Silent (SNP) | VAF 24/137 reads (18%) | catalogued as COSV100462388; called by muse, mutect2, varscan2
- MAG | c.12C>G p.L4= | Silent (SNP) | VAF 77/515 reads (15%) | catalogued as COSV100728032, COSV62700832; called by muse, mutect2, varscan2
- MAP2K7 | c.324C>T p.I108= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs775833934, COSV101209127; called by muse, mutect2, varscan2
- MAP2K7 | c.561C>A p.I187= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs747687849, COSV101209129; called by muse, mutect2, varscan2
- MAP3K11 | c.972C>G p.G324= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as COSV100482715; called by muse, mutect2, varscan2
- MCOLN1 | c.1530C>T p.L510= | Silent (SNP) | VAF 67/340 reads (20%) | catalogued as COSV99654417; called by muse, mutect2, varscan2
- MED1 | c.207C>G p.L69= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV100328115; called by muse, mutect2, varscan2
- MED11 | c.183G>A p.A61= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV99543554; called by muse, mutect2, varscan2
- MGA | c.5434C>T p.L1812= (on ENST00000219905 / NM_001164273.1; = p.L1603= on NM_001080541.2) | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV99581332; called by muse, mutect2, varscan2
- MRPL27 | c.24G>A p.L8= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV99869115; called by muse, mutect2, varscan2
- MTF2 | c.234C>T p.I78= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as rs1318429064, COSV100940177; called by muse, mutect2, varscan2
- MYH14 | c.5388C>T p.F1796= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as COSV99223877; called by muse, mutect2, varscan2
- MYH4 | c.1491C>T p.F497= | Silent (SNP) | VAF 20/141 reads (14%) | catalogued as rs756760953, COSV55116044; called by muse, mutect2, varscan2
- MYH7 | c.4608G>A p.E1536= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as COSV62524194; called by muse, mutect2, varscan2
- MYO7B | c.168C>G p.L56= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV101268368; called by muse, mutect2, varscan2
- NAALADL2 | c.1035C>T p.F345= | Silent (SNP) | VAF 34/138 reads (25%) | catalogued as rs983821275; called by muse, mutect2
- NCKIPSD | c.480C>T p.L160= | Silent (SNP) | VAF 57/274 reads (21%) | catalogued as COSV99584220; called by muse, mutect2, varscan2
- NCOA6 | c.453A>T p.G151= | Silent (SNP) | VAF 18/111 reads (16%) | catalogued as COSV100750291; called by muse, mutect2, varscan2
- NRG3 | c.1101C>T p.I367= | Silent (SNP) | VAF 17/112 reads (15%) | catalogued as COSV64580349, COSV64589160; called by muse, mutect2, varscan2
- NRXN1 | c.357C>T p.I119= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs200494288, COSV101280002, COSV68008092; called by muse, mutect2, varscan2
- NSD3 | c.2958G>T p.L986= | Silent (SNP) | VAF 17/121 reads (14%) | catalogued as COSV57671702; called by muse, mutect2, varscan2
- NTN3 | c.672C>G p.L224= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV99565253; called by muse, mutect2, varscan2
- NUMA1 | c.5742G>T p.L1914= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as COSV99474968; called by muse, mutect2, varscan2
- NUMA1 | c.3675C>T p.S1225= | Silent (SNP) | VAF 35/145 reads (24%) | catalogued as COSV100706556; called by muse, mutect2, varscan2
- OBSCN | c.12456C>G p.L4152= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs942055797, COSV99483491; called by muse, varscan2
- OBSCN | c.22791C>A p.G7597= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as COSV100805342; called by muse, mutect2, varscan2
- OR10A4 | c.774C>T p.L258= | Silent (SNP) | VAF 20/123 reads (16%) | catalogued as COSV101139586; called by muse, mutect2, varscan2
- OR10K2 | c.351C>T p.V117= | Silent (SNP) | VAF 28/114 reads (25%) | catalogued as COSV100149409, COSV100149637; called by muse, mutect2, varscan2
- OR11H12 | c.450C>T p.I150= | Silent (SNP) | VAF 38/277 reads (14%) | catalogued as COSV73569136; called by muse, mutect2, varscan2
- OR2K2 | c.612C>T p.H204= (on ENST00000374428; = p.H175= on NM_205859.2) | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV100235428; called by muse, varscan2
- OR2T11 | c.48G>A p.V16= | Silent (SNP) | VAF 22/117 reads (19%) | catalogued as COSV100424935; called by muse, mutect2, varscan2
- OR5T3 | c.78G>A p.L26= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV100282920, COSV57380515; called by muse, mutect2, varscan2
- PAPLN | c.3345C>T p.F1115= (on ENST00000554301; = p.F1088= on NM_173462.4) | Silent (SNP) | VAF 22/105 reads (21%) | catalogued as COSV99390337; called by muse, mutect2, varscan2
- PARK7 | c.171C>T p.S57= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV100096765; called by muse, mutect2, varscan2
- PIGC | c.888C>T p.L296= | Silent (SNP) | VAF 28/179 reads (16%) | catalogued as rs375726386; called by muse, mutect2, varscan2
- PIGU | c.855C>T p.F285= | Silent (SNP) | VAF 32/165 reads (19%) | catalogued as rs367848167; called by muse, mutect2, varscan2
- PKHD1 | c.9058C>T p.L3020= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as rs779074962, COSV100584376; called by muse, mutect2, varscan2
- PLCL1 | c.1332C>G p.L444= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs952717931, COSV101407263, COSV70830792; called by muse, mutect2, varscan2
- PLEC | c.12165C>T p.I4055= (on ENST00000322810 / NM_201380.4; = p.I3945= on NM_000445.5) | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs781980270, COSV100518311; ClinVar: likely benign; called by muse, mutect2
- PMFBP1 | c.597G>A p.V199= | Silent (SNP) | VAF 44/268 reads (16%) | catalogued as COSV99401447; called by muse, mutect2, varscan2
- POMZP3 | c.75G>A p.Q25= | Silent (SNP) | VAF 41/179 reads (23%) | catalogued as COSV51887968, COSV99300657; called by muse, mutect2, varscan2
- PPP1R15A | c.2024G>A p.*675= | Silent (SNP) | VAF 30/163 reads (18%) | catalogued as COSV52338910, COSV99566252; called by muse, mutect2, varscan2
- PRTG | c.2223C>T p.H741= | Silent (SNP) | VAF 32/131 reads (24%) | catalogued as COSV101221477; called by muse, mutect2, varscan2
- PRUNE1 | c.1284C>G p.L428= | Silent (SNP) | VAF 44/233 reads (19%) | catalogued as COSV99639885; called by muse, mutect2, varscan2
- PTPRS | c.5760G>A p.P1920= | Silent (SNP) | VAF 26/158 reads (16%) | catalogued as rs766060117, COSV99512142; called by muse, mutect2, varscan2
- PTPRU | c.2790G>A p.V930= | Silent (SNP) | VAF 24/123 reads (20%) | catalogued as COSV100113617; called by muse, mutect2, varscan2
- PYROXD2 | c.1596C>T p.F532= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as rs369487361; called by muse, mutect2, varscan2
- RAI1 | c.5505C>T p.V1835= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV99883955; called by muse, mutect2, varscan2
- RASGRF2 | c.132C>T p.F44= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV99430133; called by muse, mutect2, varscan2
- RBP3 | c.3210G>A p.K1070= | Silent (SNP) | VAF 17/105 reads (16%) | called by muse, mutect2, varscan2
- RCN1 | c.858G>A p.R286= | Silent (SNP) | VAF 19/100 reads (19%) | catalogued as COSV99277428; called by muse, mutect2, varscan2
- RMI1 | c.513A>G p.G171= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV100366453; called by muse, mutect2, varscan2
- RNF146 | c.57G>A p.R19= (on ENST00000368314 / NM_001242850.2; = p.R18= on NM_030963.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 16/97 reads (16%) | catalogued as COSV100541889; called by muse, mutect2, varscan2
- RNF213 | c.2769C>T p.L923= | Silent (SNP) | VAF 23/136 reads (17%) | catalogued as rs762209364, COSV100173898; called by muse, mutect2, varscan2
- RPL3L | c.1023G>A p.K341= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as COSV51905331, COSV99238464; called by muse, mutect2, varscan2
- RPRD1A | c.180C>G p.L60= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV100036398; called by muse, mutect2, varscan2
- RPS15A | c.249C>G p.L83= | Silent (SNP) | VAF 14/192 reads (7%) | catalogued as COSV100540019; called by muse, mutect2
- RTTN | c.1422C>T p.I474= | Silent (SNP) | VAF 25/124 reads (20%) | catalogued as rs779011598, COSV55344017; called by muse, mutect2, varscan2
- SAMD9 | c.3307C>T p.L1103= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as rs746799013, COSV101180353, COSV66073005; called by muse, mutect2, varscan2
- SCN4A | c.2349C>T p.L783= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as rs1304600709, COSV101438635; called by muse, mutect2, varscan2
- SCRIB | c.405G>A p.L135= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as COSV100254023; called by muse, mutect2, varscan2
- SH3TC2 | c.3387C>T p.F1129= | Silent (SNP) | VAF 34/169 reads (20%) | catalogued as COSV100102281; called by muse, mutect2, varscan2
- SIGLEC8 | c.1461G>A p.L487= | Silent (SNP) | VAF 38/115 reads (33%) | catalogued as rs377081569; called by muse, mutect2, varscan2
- SLC27A1 | c.1860C>T p.F620= | Silent (SNP) | VAF 24/119 reads (20%) | catalogued as COSV99393607; called by muse, mutect2, varscan2
- SLC32A1 | c.498C>T p.L166= | Silent (SNP) | VAF 6/120 reads (5%) | catalogued as COSV99462595; called by muse, mutect2
- SLC6A19 | c.549C>T p.I183= | Silent (SNP) | VAF 35/161 reads (22%) | catalogued as rs777423162, COSV100443732; called by muse, mutect2, varscan2
- SLIT3 | c.387C>T p.F129= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV60609097; called by muse, mutect2, varscan2
- SLITRK3 | c.2862C>T p.L954= | Silent (SNP) | VAF 54/198 reads (27%) | catalogued as rs1440111685, COSV53847232; called by muse, mutect2, varscan2
- SMAP1 | c.1383C>G p.L461= (on ENST00000370455 / NM_001044305.3; = p.L434= on NM_021940.5) | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as COSV100017377; called by muse, mutect2, varscan2
- SNTB2 | c.1401C>T p.F467= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs772314867, COSV100293443; called by muse, mutect2, varscan2
- SNX18 | c.1422C>T p.L474= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV100410509; called by muse, mutect2, varscan2
- SP1 | c.1425G>A p.Q475= (on ENST00000327443 / NM_138473.3; = p.Q468= on NM_003109.1) | Silent (SNP) | VAF 24/174 reads (14%) | catalogued as COSV100540827; called by muse, mutect2, varscan2
- SPRED2 | c.999G>C p.V333= | Silent (SNP) | VAF 25/180 reads (14%) | catalogued as COSV100710328; called by muse, mutect2, varscan2
- SPTBN5 | c.7744C>T p.L2582= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV100312093; called by muse, mutect2, varscan2
- SSRP1 | c.1545G>A p.K515= | Silent (SNP) | VAF 28/122 reads (23%) | catalogued as COSV99555102; called by muse, mutect2, varscan2
- STAB2 | c.801C>G p.G267= | Silent (SNP) | VAF 10/116 reads (9%) | catalogued as COSV101186264, COSV66335649; called by muse, mutect2
- STOX1 | c.2715C>T p.N905= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as rs771103100, COSV100058199; called by muse, mutect2, varscan2
- SWAP70 | c.741G>C p.L247= | Silent (SNP) | VAF 25/139 reads (18%) | catalogued as rs1164580320, COSV100014087; called by muse, mutect2, varscan2
- SWSAP1 | c.105C>T p.G35= (on ENST00000312423; = p.G56= on NM_175871.4) | Silent (SNP) | VAF 50/197 reads (25%) | catalogued as COSV99710287; called by muse, mutect2, varscan2
- SYNE1 | c.23640G>A p.L7880= (on ENST00000367255 / NM_182961.4; = p.L7809= on NM_033071.3) | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV99576319; called by muse, mutect2, varscan2
- SYNE1 | c.15249G>A p.Q5083= (on ENST00000367255 / NM_182961.4; = p.Q5012= on NM_033071.3) | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as COSV99576323; called by muse, mutect2, varscan2
- SYNRG | c.2922C>G p.T974= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as rs746515222; called by muse, mutect2, varscan2
- TAB1 | c.1386C>T p.F462= | Silent (SNP) | VAF 17/123 reads (14%) | catalogued as COSV99336261; called by muse, mutect2, varscan2
- TACC2 | c.288C>T p.P96= | Silent (SNP) | VAF 32/126 reads (25%) | catalogued as COSV100553602; called by muse, mutect2, varscan2
- TACC2 | c.8643G>A p.A2881= (on ENST00000334433; = p.A959= on NM_006997.4) | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs376082640, COSV53292187, COSV99587085; called by mutect2, varscan2
- TBCD | c.471C>T p.L157= | Silent (SNP) | VAF 62/334 reads (19%) | catalogued as COSV100833676; called by muse, mutect2, varscan2
- TBX22 | c.465C>G p.V155= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV100960932; called by muse, mutect2, varscan2
- TDRD5 | c.1788G>A p.V596= | Silent (SNP) | VAF 9/94 reads (10%) | catalogued as COSV99677006; called by muse, mutect2
- TIMD4 | c.273G>A p.P91= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as rs774244018, COSV50854024, COSV99192883; called by muse, mutect2, varscan2
- TLE1 | c.840G>A p.K280= | Silent (SNP) | VAF 26/154 reads (17%) | catalogued as COSV100916353; called by muse, mutect2, varscan2
- TMEM132A | c.585C>T p.F195= | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as COSV99136986; called by muse, mutect2, varscan2
- TNC | c.1026G>A p.G342= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as COSV100405306; called by muse, mutect2, varscan2
- TNIP2 | c.669C>G p.L223= | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as COSV100198745; called by muse, mutect2
- TPH1 | c.261C>G p.L87= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as rs753686032, COSV100001062; called by muse, mutect2, varscan2
- TPM4 | c.120G>C p.V40= (on ENST00000300933; = p.D48H on NM_003290.3) | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV99959531; called by muse, mutect2, varscan2
- TRAK1 | c.2457G>A p.L819= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV100565841, COSV59645561; called by muse, mutect2, varscan2
- TRAV12-3 | c.99C>G p.L33= | Silent (SNP) | VAF 14/84 reads (17%) | called by muse, mutect2, varscan2
- TRIM67 | c.2325G>A p.L775= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs992038385, COSV100792199; called by muse, mutect2, varscan2
- TRMT1L | c.561C>T p.I187= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV100834737; called by muse, mutect2
- TRPM8 | c.3000C>T p.F1000= | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as COSV100224467; called by muse, mutect2, varscan2
- TSHZ1 | c.2316G>A p.A772= (on ENST00000580243 / NM_001308210.2; = p.A727= on NM_005786.6) | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs780962759, COSV59016082; called by muse, mutect2, varscan2
- TSNAXIP1 | c.1272C>T p.F424= | Silent (SNP) | VAF 37/159 reads (23%) | catalogued as rs1240624084, COSV54649491, COSV99535327; called by muse, mutect2, varscan2
- TTC16 | c.333C>T p.F111= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as COSV100077056; called by muse, mutect2, varscan2
- UNC45A | c.285C>G p.L95= | Silent (SNP) | VAF 23/127 reads (18%) | catalogued as COSV100376628; called by muse, mutect2, varscan2
- UNC79 | c.4821G>C p.L1607= (on ENST00000393151 / NM_001346218.2; = p.L1430= on NM_020818.5) | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as COSV56398297, COSV56416782, COSV99829658; called by muse, mutect2, varscan2
- URI1 | c.597G>A p.V199= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV100369191; called by muse, mutect2, varscan2
- USH2A | c.4938C>G p.V1646= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100241458; called by muse, mutect2, varscan2
- USP4 | c.2352C>G p.L784= | Silent (SNP) | VAF 31/114 reads (27%) | catalogued as COSV99649679; called by muse, mutect2, varscan2
- VEZF1 | c.886C>T p.L296= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as rs1209167324, COSV51968863, COSV99365597; called by muse, mutect2, varscan2
- VPS13C | c.1215C>G p.L405= (on ENST00000644861 / NM_020821.3; = p.L362= on NM_017684.5) | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV51223136; called by muse, mutect2, varscan2
- VRTN | c.942C>T p.F314= | Silent (SNP) | VAF 16/165 reads (10%) | catalogued as rs749268902, COSV99832451; called by muse, mutect2
- VSIG4 | c.195C>T p.V65= | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as COSV101038292; called by muse, mutect2, varscan2
- ZAP70 | c.1533C>T p.I511= | Silent (SNP) | VAF 48/281 reads (17%) | catalogued as COSV53856177, COSV99385884; called by muse, mutect2, varscan2
- ZFP69B | c.627C>T p.I209= | Silent (SNP) | VAF 18/204 reads (9%) | catalogued as COSV100848302; called by muse, mutect2
- ZGRF1 | c.4669C>T p.L1557= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV100349342, COSV58342813; called by muse, mutect2, varscan2
- ZNF217 | c.168C>T p.V56= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as COSV100184776, COSV56599693; called by muse, mutect2
- ZNF229 | c.235C>T p.L79= | Silent (SNP) | VAF 16/129 reads (12%) | catalogued as COSV99350838; called by muse, mutect2, varscan2
- ZNF394 | c.1233G>A p.E411= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV100529962; called by muse, mutect2, varscan2
- ZNF45 | c.1182G>A p.G394= | Silent (SNP) | VAF 16/122 reads (13%) | catalogued as COSV99524247; called by muse, mutect2, varscan2
- ZNF532 | c.1959C>G p.L653= | Silent (SNP) | VAF 26/115 reads (23%) | catalogued as COSV100267100, COSV60173143; called by muse, mutect2, varscan2
- ZNF585B | c.492G>C p.G164= | Silent (SNP) | VAF 32/104 reads (31%) | catalogued as rs772335554, COSV100459616; called by muse, mutect2, varscan2
- ZNF71 | c.1437G>C p.T479= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as COSV100046078, COSV100046260; called by muse, mutect2, varscan2
- ZNRF3 | c.549G>A p.V183= (on ENST00000544604 / NM_001206998.2; = p.V83= on NM_032173.3) | Silent (SNP) | VAF 16/108 reads (15%) | catalogued as COSV100238920; called by muse, mutect2, varscan2
- COPZ2 | c.112-288G>A | Intron (SNP) | VAF 19/90 reads (21%) | catalogued as rs1235835949, COSV99133785; called by muse, mutect2, varscan2
- CXCL16 | c.-53C>A | 5'UTR (SNP) | VAF 5/36 reads (14%) | catalogued as COSV52644320, COSV99351770; called by muse, mutect2, varscan2
- GRHL3 | c.1694+4283C>T | Intron (SNP) | VAF 16/77 reads (21%) | catalogued as COSV99134384; called by muse, mutect2
- IGLL5 | chr22:22900997 C>T | 3'Flank (SNP) | VAF 16/95 reads (17%) | catalogued as rs1220496210; called by muse, mutect2, varscan2
- LYPLAL1 | c.-1G>A | 5'UTR (SNP) | VAF 9/84 reads (11%) | catalogued as COSV100859725; called by muse, mutect2, varscan2
- PRKN | c.1083+3430del | Intron (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel, varscan2
- SLC3A2 | chr11:62853378 C>G | 5'Flank (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- TRIM24 | c.*950G>A | 3'UTR (SNP) | VAF 11/76 reads (14%) | catalogued as COSV58975090; called by muse, mutect2
- TTN | c.10360+4919C>A | Intron (SNP) | VAF 7/48 reads (15%) | catalogued as COSV60179573, COSV60181801; called by muse, mutect2, varscan2
